Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A1AS, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A1AS-01A (Primary Tumor).

ICD-0-3

Carcinoma, infiltrating duct, NOS 8500/3

Site Code: breast, NOS C50.9

12/21/10 lw

Final Diagnosis

Breast, left, wide local excision: Infiltrating ductal carcinoma, Nottingham grade II (of III) [tubules 2/3, nuclei 2/3, mitoses 3/3; Nottingham score 7/9], forming multiple (2) masses (0.7 x 0.3 x 0.3 cm and 4.3 x 3.4 x 3.2 cm [AJCC pT2]. Angiolymphatic invasion is present. The non-neoplastic breast parenchyma shows nonproliferative fibrocystic changes. All surgical resection margins, after separately submitted re-excisions of new deep/inferior, new anterior/inferior medial aspect, new medial/anterior, new medial/deep, new lateral, and new posterior/medial margins, are negative for tumor (minimum tumor free margin, 1.0 cm, new medial/anterior and new medial/deep margins).

Lymph nodes, left high axillary, dissection: Multiple (5) left high axillary lymph nodes are negative for tumor.

Lymph nodes, left mid/low axillary, dissection: A single (of 12) left mid/low axillary lymph node is positive for metastatic adenocarcinoma. The positive lymph node measures 1.0 x 0.9 x 0.7 cm.

Faxitron done.

Source: NCI Genomic Data Commons file eb8649d8-fc17-4b7e-8c7d-5ea1801da9f4 (TCGA-AR-A1AS.180AA688-0B63-4DD9-BA29-708E80FBC4C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).